Gene-level copy-number profile of tumor specimen HCM-SANG-1088-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-1088-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G1.
Specimen HCM-SANG-1088-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b1c8915a-9a5d-4e22-bcc6-6057d3995c8e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1088-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,749 have no estimate.
https://portal.gdc.cancer.gov/files/25b5feb7-39ba-4479-b599-0078d7cf8d5b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,661; copy number 2: 18,766; copy number 3: 28,889; copy number 4: 3,926; copy number 5: 3,902; copy number 6: 380; copy number 7: 390; copy number 8: 945; copy number 10: 3.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,190,901–7,200,857, 2 genes: RPS3AP33, AF228730.1.
- chr8:12,064,389–12,177,550, 10 genes (within-gene range 0–1): DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,338 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:137,682–157,887, 3 genes, copy number 10: AL627309.7, AL627309.2, RNU6-1100P.
- chr13:18,467,172–45,418,455, 523 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr13:45,464,898–114,337,626, 803 genes, copy number 7–8 (broad region; genes not listed).
- chr21:8,603,547–8,701,562, 3 genes, copy number 7: RPSAP68, CR381572.2, CR381572.1.
- chr21:10,482,738–10,649,835, 6 genes, copy number 7 (within-gene range 3–7): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1.

Autosomal genes at a single copy (total copy number 1): 1,109. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
